CCDI case PBCMGW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aa2c277e-d340-489e-b4e4-f8248641b846

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,863 days).

Biospecimens (2 samples)
- Sample 0DVJNO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
